TARGET case TARGET-40-NAAHDA — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dcd319b3-7072-5659-83c7-97923cde0d9b

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 1,242 days (3.4 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 15.0 years (5,481 days); Year of diagnosis: 2007; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,242 days (3.4 years).
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 855 days (2.3 years); Progression or recurrence: Yes; Days to progression: 855 days (2.3 years); Days to first event: 855 days (2.3 years); First event: Relapse.
- Days to follow up: 1,242 days (3.4 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2010.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHDA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHDA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1242
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Pelvis
- Specific tumor site: Ilium
- Definitive Surgery: Amputation and hemipvelvectomy
- Primary site progression: Yes
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Percent necrosis at Definitive Surgery: >90
